Somatic mutation profile of tumor specimen TCGA-34-2596-01A (aliquot TCGA-34-2596-01A-01W-0877-08) from TCGA case TCGA-34-2596, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.0 years (25,574 days).
Specimen TCGA-34-2596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81156747-4704-475b-918d-becb7a1a0a20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2596-11A (Solid Tissue Normal), aliquot TCGA-34-2596-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9577a620-2ebf-4b5c-a3c5-fa04742eb937

The open-access MAF lists 259 somatic variants for this specimen: 188 protein-altering or splice-affecting, 65 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 65, Nonsense Mutation 11, Frame Shift Del 5, Frame Shift Ins 5, Splice Site 4, RNA 3, Intron 2, Translation Start Site 1, In Frame Del 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 35/90 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519921, COSV67960034, COSV67960332, COSV67961305; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYT13 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 42/74 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- ABCA9 | c.1309T>C p.F437L | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV60624659; called by muse, mutect2, varscan2
- ABHD13 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65534761, COSV65534896; called by muse, mutect2
- ACOX3 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62711959; called by muse, mutect2, varscan2
- ACTL9 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782777098, COSV61005735; called by muse, mutect2, varscan2
- ADAM9 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs147636313; called by muse, mutect2, varscan2
- ADAMTS17 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51480229; called by muse, mutect2, varscan2
- AKAP11 | c.4498G>T p.E1500* | Nonsense Mutation (SNP) | VAF 120/207 reads (58%) | catalogued as COSV50296912; called by muse, mutect2, varscan2
- AMPH | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV100341604; called by mutect2, varscan2
- ANKRD11 | c.2676C>G p.S892R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV56360693; called by muse, mutect2, varscan2
- ARFGEF1 | c.3508G>C p.V1170L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51608294; called by muse, mutect2, varscan2
- ARID2 | c.4391G>A p.R1464H | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs770601353, COSV57603414; called by muse, mutect2, varscan2
- ATG13 | c.1348-1G>C p.X450_splice (on ENST00000359513 / NM_001346321.1; = p.X413_splice on NM_014741.4 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 68/135 reads (50%) | catalogued as COSV56319316; called by muse, mutect2, varscan2
- ATP4A | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV52867955; called by muse, mutect2, varscan2
- BFSP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV56588805; called by muse, mutect2, varscan2
- BMPR2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs777927015, COSV65807366; called by muse, mutect2
- BRAF | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 293/446 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56174024; called by muse, mutect2, varscan2
- BRINP3 | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 429/1489 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1471961126, COSV66523813; called by muse, mutect2, varscan2
- C12orf50 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV53895191; called by muse, mutect2, varscan2
- C2orf16 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV68646040; called by muse, mutect2, varscan2
- C6 | c.1524G>T p.R508S | Missense Mutation (SNP) | VAF 156/456 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV54706817, COSV54709914; called by muse, mutect2, varscan2
- CALCR | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745444864, COSV64008031; called by muse, mutect2, varscan2
- CBLN1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV54653505; called by muse, mutect2, varscan2
- CCM2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51848265; called by muse, mutect2, varscan2
- CD1D | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63808990, COSV63809555; called by muse, mutect2, varscan2
- CDH23 | c.9350T>C p.M3117T | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV56462904; called by muse, mutect2, varscan2
- CFAP251 | c.2927G>C p.R976T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56610378; called by muse, mutect2, varscan2
- CHAMP1 | c.1987A>G p.I663V | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782559791, COSV63522339; called by muse, mutect2, varscan2
- CLCN2 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55601093, COSV55601563; called by muse, mutect2
- CNOT2 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 130/386 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV57502658; called by muse, mutect2, varscan2
- CNTN4 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV61872800; called by muse, mutect2, varscan2
- COL15A1 | c.3561C>A p.D1187E | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); catalogued as COSV66644560; called by muse, mutect2, varscan2
- COL19A1 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV59572602; called by muse, mutect2, varscan2
- COLEC12 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68370467; called by muse, mutect2, varscan2
- CREBRF | c.1650A>T p.K550N | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51633022; called by muse, mutect2, varscan2
- CTSA | c.535T>G p.Y179D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51942092; called by muse, mutect2, varscan2
- CXCL14 | c.281G>A p.R94H (on ENST00000337225; = p.R82H on NM_004887.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs139612389; called by muse, mutect2, varscan2
- CYP2A13 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV57837730; called by muse, mutect2
- DCT | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 52/112 reads (46%) | catalogued as COSV65469020; called by muse, mutect2, varscan2
- DENND1B | c.1883A>G p.E628G | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54148746; called by muse, mutect2, varscan2
- DIRAS2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759324657, COSV65370326; called by muse, mutect2, varscan2
- DLG2 | c.1011C>A p.D337E | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54638779, COSV54643067; called by muse, mutect2, varscan2
- DNAH11 | c.6665G>C p.R2222P | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60955240; called by muse, mutect2, varscan2
- DNAH7 | c.10795G>T p.G3599W | Missense Mutation (SNP) | VAF 113/284 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56764327; called by muse, mutect2, varscan2
- DNASE1L3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 1194/1557 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs201136542; called by muse, mutect2, varscan2
- DNMT3A | c.2632T>C p.S878P | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53051897; called by muse, mutect2, varscan2
- DPPA2 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 91/384 reads (24%) | catalogued as COSV72118070; called by muse, mutect2, varscan2
- ECPAS | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52196899; called by muse, mutect2, varscan2
- EFHC2 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV101375487, COSV69553733; called by muse, mutect2, varscan2
- EGF | c.1912A>T p.S638C | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54478561; called by muse, mutect2, varscan2
- EHBP1 | c.2189G>T p.S730I | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.125); catalogued as rs755521829, COSV50419949; called by muse, mutect2, varscan2
- EIPR1 | c.517-2A>T p.X173_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV66129657; called by muse, mutect2
- ENPEP | c.1561del p.A521Qfs*11 | Frame Shift Del (DEL) | VAF 53/132 reads (40%) | catalogued as COSV99487966; called by mutect2, pindel, varscan2
- EPB41L3 | c.3142G>A p.D1048N | Missense Mutation (SNP) | VAF 125/239 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59453166; called by muse, mutect2, varscan2
- EPHA7 | c.2172+1G>T p.X724_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV65182463; called by muse, mutect2, varscan2
- FATE1 | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64848975; called by muse, mutect2, varscan2
- FBXO22 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 227/737 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV57617450; called by muse, mutect2, varscan2
- FLG | c.2993C>A p.S998Y | Missense Mutation (SNP) | VAF 146/378 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV64241681; called by muse, mutect2, varscan2
- FMN2 | c.2905C>A p.P969T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1490064373, COSV60429880; called by muse, mutect2, varscan2
- FRG2B | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV71042699, COSV71043031; called by muse, mutect2
- GALNTL6 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV72490894; called by muse, mutect2, varscan2
- GNL3L | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60575886, COSV60576305, COSV60577880; called by muse, mutect2, varscan2
- GOLGB1 | c.4004A>T p.K1335I | Missense Mutation (SNP) | VAF 211/483 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61465669; called by muse, mutect2, varscan2
- GRM6 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51440744; called by mutect2, varscan2
- HDAC9 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as rs761522691, COSV67772931; called by muse, mutect2, varscan2
- HEATR6 | c.2319C>A p.N773K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV51745637; called by muse, mutect2, varscan2
- HNF1A | c.1388A>G p.Q463R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV57461984; called by muse, mutect2, varscan2
- HSP90B1 | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV55355297, COSV55355769; called by muse, mutect2, varscan2
- HYAL3 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56497526; called by muse, mutect2, varscan2
- IARS1 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65115156; called by muse, mutect2, varscan2
- IFT52 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65975022; called by muse, mutect2, varscan2
- IGHV6-1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 102/181 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs373934455; called by muse, mutect2, varscan2
- IGLV8-61 | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 107/403 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV66503192; called by muse, mutect2, varscan2
- IL10RA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV57140558; called by muse, mutect2, varscan2
- IQCB1 | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 239/722 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60437399; called by muse, varscan2
- KCNB2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050150; called by muse, mutect2, varscan2
- KIF16B | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61701315, COSV61706002; called by muse, mutect2, varscan2
- KLHL14 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 121/195 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV63832351; called by muse, mutect2, varscan2
- KLHL23 | c.1075A>T p.R359W | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55867128; called by muse, mutect2, varscan2
- KLHL7 | c.1136C>T p.A379V (on ENST00000339077 / NM_001031710.3; = p.A331V on NM_018846.5) | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.607); catalogued as COSV59161326; called by muse, mutect2, varscan2
- KMT2D | c.16329C>A p.Y5443* | Nonsense Mutation (SNP) | VAF 72/278 reads (26%) | catalogued as COSV56438863; called by muse, mutect2, varscan2
- KNG1 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV53977683; called by muse, mutect2, varscan2
- KRT24 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224997746, COSV52880224; called by muse, mutect2, varscan2
- LGSN | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65726571, COSV65727179; called by muse, mutect2, varscan2
- LRP1B | c.4195G>T p.A1399S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV67210016, COSV67218175; called by muse, mutect2, varscan2
- MORF4L2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 111/148 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100846405, COSV64610634, COSV64610988; called by muse, mutect2, varscan2
- MUC16 | c.32662G>T p.V10888L | Missense Mutation (SNP) | VAF 407/1323 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV67464969; called by muse, mutect2, varscan2
- MUC16 | c.16405C>T p.P5469S | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV67464976; called by muse, mutect2, varscan2
- MYBPC1 | c.1452-1G>T p.X484_splice (on ENST00000550270 / NM_206820.2; = p.X509_splice on NM_002465.4) | Splice Site (SNP) | VAF 94/374 reads (25%) | catalogued as COSV62252969; called by muse, mutect2, varscan2
- MYBPC1 | c.2341G>T p.D781Y (on ENST00000550270 / NM_206820.2; = p.D788Y on NM_002465.4) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62252980; called by muse, mutect2, varscan2
- MYOF | c.495dup p.P166Afs*30 | Frame Shift Ins (INS) | VAF 16/196 reads (8%) | catalogued as rs764027281; called by mutect2*, pindel
- MYRIP | c.2126A>G p.Y709C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56868755; called by muse, mutect2, varscan2
- NDRG1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV60483088; called by muse, mutect2, varscan2
- NME9 | c.719A>T p.D240V (on ENST00000333911 / NM_001349024.2; = p.D179V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 297/925 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV58618621; called by muse, mutect2, varscan2
- NPHS1 | c.3368G>T p.R1123L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62287760, COSV62288416; called by muse, mutect2, varscan2
- NRROS | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs150316796, COSV60745860; called by muse, mutect2
- NUP155 | c.2810C>T p.A937V (on ENST00000231498 / NM_153485.3; = p.A878V on NM_004298.4) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51529774; called by muse, mutect2, varscan2
- OR1L4 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV52340409; called by muse, varscan2
- OR2M7 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 217/703 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58739002; called by muse, mutect2, varscan2
- OR2T10 | c.263A>T p.K88I | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV57896830; called by muse, mutect2, varscan2
- OR4D5 | c.139del p.V47Sfs*2 | Frame Shift Del (DEL) | VAF 129/314 reads (41%) | catalogued as COSV58310318; called by mutect2, pindel, varscan2
- OR4K14 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV59292829; called by muse, mutect2
- OR4K15 | c.194G>T p.G65V (on ENST00000305051; = p.G41V on NM_001005486.1) | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59301355; called by muse, mutect2, varscan2
- OR8B2 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV66664651; called by muse, mutect2, varscan2
- OR8J3 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV56880694; called by muse, mutect2, varscan2
- PAPPA | c.2513C>G p.P838R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60283040; called by muse, mutect2, varscan2
- PARPBP | c.774T>A p.N258K | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV59673459; called by muse, mutect2, varscan2
- PATZ1 | c.2063G>C p.*688Sext*30 | Nonstop Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56743656; called by muse, mutect2
- PBXIP1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs760022387, COSV63777196; called by mutect2, varscan2
- PCDHB12 | c.2168del p.G723Vfs*17 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs781960815, COSV53394560; called by mutect2, pindel, varscan2
- PCDHGA8 | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs781200096, COSV53945519; called by muse, mutect2, varscan2
- PDIA5 | c.1554G>T p.E518D | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV60249085; called by muse, mutect2, varscan2
- PLA2G4F | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs779506232, COSV51826835; called by muse, mutect2, varscan2
- PLCB4 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV53801365; called by muse, mutect2, varscan2
- PLCD1 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52184612; called by muse, mutect2
- PRELP | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs147252422, COSV100557816; called by muse, mutect2, varscan2
- PRKCI | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55518932; called by muse, mutect2, varscan2
- PRUNE2 | c.6677C>G p.P2226R | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV65041403; called by muse, mutect2, varscan2
- RASGRF1 | c.1895T>A p.V632D | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67249959; called by muse, mutect2, varscan2
- RGL1 | c.1117A>T p.T373S (on ENST00000360851 / NM_001297672.2; = p.T408S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.5); catalogued as COSV58985172; called by muse, mutect2, varscan2
- RGS22 | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62661491, COSV62666829; called by muse, mutect2, varscan2
- RIN3 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV53648277; called by muse, mutect2, varscan2
- RXFP4 | c.470G>C p.W157S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV100562977, COSV58145079; called by muse, mutect2, varscan2
- RYR3 | c.1266C>A p.V422= | Splice Region (SNP) | VAF 197/594 reads (33%) | catalogued as COSV66788538; called by muse, mutect2, varscan2
- RYR3 | c.6989G>T p.G2330V (on ENST00000389232; = p.G2331V on NM_001036.6) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109649; called by muse, mutect2, varscan2
- SAMD4B | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58751477; called by muse, mutect2, varscan2
- SEL1L2 | c.561T>G p.F187L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53152093; called by muse, mutect2, varscan2
- SETX | c.4181C>T p.S1394L | Missense Mutation (SNP) | VAF 178/527 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56384759; called by muse, mutect2, varscan2
- SHISA2 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1287524506, COSV60110762; called by muse, mutect2, varscan2
- SIGLEC10 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV59481562; called by mutect2, varscan2
- SLC22A7 | c.434G>C p.R145T (on ENST00000372585 / NM_153320.2; = p.R143T on NM_006672.3) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV65354361; called by muse, mutect2, varscan2
- SLCO1C1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56868350, COSV56872385; called by muse, mutect2, varscan2
- SPATA31E1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV57791361; called by muse, mutect2, varscan2
- SPECC1L | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58658367; called by muse, mutect2, varscan2
- SSBP1 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV54681257; called by muse, mutect2, varscan2
- STAB2 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66338753; called by muse, mutect2, varscan2
- SUN5 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV62181084, COSV62181720; called by muse, mutect2, varscan2
- SYNE4 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV53324621; called by muse, mutect2, varscan2
- TAPBP | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV69667272; called by muse, mutect2
- TBATA | c.706T>C p.C236R | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV54719082; called by muse, mutect2, varscan2
- TBCD | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62800851; called by muse, mutect2, varscan2
- TCF20 | c.3614G>A p.G1205E | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59491060; called by muse, mutect2, varscan2
- THBS2 | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs769719849, COSV64678774, COSV64682665; called by muse, mutect2, varscan2
- TMCC1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 86/522 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV67873006; called by muse, mutect2, varscan2
- TMEM132D | c.2840A>G p.H947R | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV67160334; called by muse, mutect2, varscan2
- TMEM132D | c.2150A>G p.D717G | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67160339; called by muse, mutect2, varscan2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 179/275 reads (65%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TRIM24 | c.1703A>C p.Q568P (on ENST00000343526 / NM_015905.3; = p.Q534P on NM_003852.4) | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.806); catalogued as COSV58972184, COSV58974125; called by muse, mutect2, varscan2
- TRIP12 | c.4786G>C p.E1596Q | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.094); catalogued as COSV52263840; called by muse, mutect2, varscan2
- TTN | c.86980G>T p.E28994* (on ENST00000591111; = p.E21570* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 92/308 reads (30%) | catalogued as COSV60049839; called by muse, mutect2, varscan2
- TTN | c.77495C>G p.P25832R (on ENST00000591111; = p.P18408R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/344 reads (5%) | PolyPhen probably damaging (0.999); catalogued as COSV60049892; called by muse, mutect2
- TTN | c.64658T>A p.V21553D (on ENST00000591111; = p.V14129D on NM_003319.4) | Missense Mutation (SNP) | VAF 158/504 reads (31%) | PolyPhen possibly damaging (0.679); catalogued as COSV59959112, COSV60049944; called by muse, varscan2
- TTN | c.52141G>A p.G17381R (on ENST00000591111; = p.G9957R on NM_003319.4) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV60049992; called by muse, mutect2, varscan2
- TTN | c.49496G>A p.R16499Q (on ENST00000591111; = p.R9075Q on NM_003319.4) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | PolyPhen benign (0.314); catalogued as rs547224785, COSV60050043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.24032A>G p.H8011R (on ENST00000591111; = p.H7084R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/470 reads (29%) | PolyPhen benign (0.009); catalogued as COSV60050097; called by muse, mutect2, varscan2
- TTN | c.659G>C p.R220P | Missense Mutation (SNP) | VAF 31/91 reads (34%) | PolyPhen possibly damaging (0.906); catalogued as COSV60000521, COSV60050122; called by muse, mutect2, varscan2
- USH1C | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017388; called by muse, mutect2, varscan2
- USH2A | c.6260A>T p.Q2087L | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56367669; called by muse, mutect2, varscan2
- UXS1 | c.1169A>T p.Y390F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as COSV51677291; called by muse, mutect2, varscan2
- VN1R1 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as COSV58091031; called by muse, mutect2, varscan2
- VPS13D | c.12635G>A p.R4212K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50637876; called by muse, mutect2
- WDR54 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV51963105; called by muse, mutect2, varscan2
- WDR72 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64746507; called by muse, mutect2, varscan2
- XDH | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 248/846 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV65148613; called by muse, mutect2, varscan2
- XYLT1 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 205/374 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54484150; called by muse, mutect2, varscan2
- ZC3H12C | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1433227668, COSV53708704; called by muse, mutect2, varscan2
- ZNF229 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV52161812; called by muse, mutect2, varscan2
- ZNF532 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 559/887 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV60173017; called by muse, mutect2, varscan2
- ZNF557 | c.421G>C p.G141R (on ENST00000414706 / NM_001044388.2; = p.G148R on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV53273830; called by muse, mutect2, varscan2
- ZNF804A | c.1607G>A p.C536Y | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV56447946; called by muse, mutect2, varscan2
- ZNF804A | c.1979C>G p.P660R | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV56447959; called by muse, mutect2, varscan2
- ZNF804B | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 66/185 reads (36%) | catalogued as COSV60827351, COSV60837421; called by muse, mutect2, varscan2
- ZNF878 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV72155997; called by muse, mutect2, varscan2
- ANKRD45 | c.58del p.E20Rfs*29 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- APOBR | c.2590G>T p.E864* (on ENST00000431282; = p.E873* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- CCDC130 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CSNK2A1 | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- DYNC2H1 | c.3809G>A p.W1270* | Nonsense Mutation (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- DYNC2I1 | c.1523dup p.L508Ffs*8 | Frame Shift Ins (INS) | VAF 67/184 reads (36%) | called by mutect2, pindel, varscan2
- GOLGA8G | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- GRIK5 | c.1734C>A p.C578* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- LRRTM1 | c.381dup p.L128Tfs*83 | Frame Shift Ins (INS) | VAF 66/169 reads (39%) | called by mutect2, pindel, varscan2
- NPS | c.244dup p.T82Nfs*19 | Frame Shift Ins (INS) | VAF 72/176 reads (41%) | called by mutect2, varscan2
- OR8B4 | c.361dup p.R121Pfs*49 | Frame Shift Ins (INS) | VAF 74/156 reads (47%) | called by mutect2, pindel, varscan2
- TMEM101 | c.35_44del p.L12Sfs*59 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1329_1337del p.M443_Y446delinsI | In Frame Del (DEL) | VAF 159/554 reads (29%) | called by mutect2, pindel, varscan2
- ADCY2 | c.1827C>T p.L609= | Silent (SNP) | VAF 24/411 reads (6%) | called by muse, mutect2
- ADGRG4 | c.2937C>T p.S979= | Silent (SNP) | VAF 875/1391 reads (63%) | catalogued as COSV54955733; called by muse, mutect2, varscan2
- ADGRL3 | c.399T>C p.I133= (on ENST00000506720 / NM_001322402.2; = p.I65= on NM_015236.6) | Silent (SNP) | VAF 96/212 reads (45%) | catalogued as COSV72268365; called by muse, mutect2, varscan2
- ANGPTL1 | c.732T>A p.G244= | Silent (SNP) | VAF 84/279 reads (30%) | catalogued as COSV52366355; called by muse, mutect2, varscan2
- ANKRD26 | c.3165A>G p.L1055= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV65775428, COSV65777230; called by muse, mutect2, varscan2
- AVPR1A | c.531G>T p.L177= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV54546497; called by muse, mutect2, varscan2
- CD22 | c.96C>T p.L32= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV50052584; called by muse, mutect2, varscan2
- CEP89 | c.1500C>T p.L500= | Silent (SNP) | VAF 14/458 reads (3%) | called by muse, mutect2
- COL4A3 | c.1824A>T p.G608= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV67415488; called by muse, mutect2, varscan2
- COMMD7 | c.558G>T p.L186= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as COSV54070169; called by muse, mutect2, varscan2
- DBR1 | c.231C>T p.L77= | Silent (SNP) | VAF 152/612 reads (25%) | catalogued as COSV53429745; called by muse, mutect2, varscan2
- DCSTAMP | c.510C>A p.T170= | Silent (SNP) | VAF 125/288 reads (43%) | catalogued as rs765227158, COSV52577620; called by muse, mutect2, varscan2
- DMD | c.10119C>T p.A3373= | Silent (SNP) | VAF 87/143 reads (61%) | catalogued as COSV58909986; called by muse, mutect2, varscan2
- DNAH11 | c.6666A>T p.R2222= | Silent (SNP) | VAF 99/396 reads (25%) | catalogued as COSV60955245; called by muse, mutect2, varscan2
- DNAJC13 | c.3741C>T p.L1247= | Silent (SNP) | VAF 113/336 reads (34%) | catalogued as rs780003866, COSV53450403; called by muse, mutect2, varscan2
- DPPA2 | c.624T>G p.P208= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV72118069; called by muse, mutect2, varscan2
- DSCAM | c.426C>A p.V142= | Silent (SNP) | VAF 116/203 reads (57%) | catalogued as COSV68624598, COSV68638199; called by muse, mutect2, varscan2
- EPO | c.69C>G p.L23= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53161393; called by muse, mutect2, varscan2
- EPS15L1 | c.1530G>A p.Q510= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV50168648; called by muse, mutect2, varscan2
- FAM135B | c.3501T>A p.P1167= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV52723926; called by muse, mutect2, varscan2
- FAM78A | c.573C>G p.T191= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1409531498, COSV55992308; called by muse, mutect2, varscan2
- FBXO42 | c.1518G>C p.L506= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV65045561; called by muse, mutect2, varscan2
- FOXC2 | c.1371C>T p.H457= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV57444314; called by muse, mutect2, varscan2
- FOXN2 | c.246T>C p.V82= | Silent (SNP) | VAF 70/163 reads (43%) | catalogued as COSV61318038; called by muse, mutect2, varscan2
- GPR151 | c.21A>G p.A7= | Silent (SNP) | VAF 109/203 reads (54%) | catalogued as COSV57037115; called by muse, mutect2, varscan2
- GRIN2A | c.4209G>C p.S1403= | Silent (SNP) | VAF 73/141 reads (52%) | catalogued as COSV58032105, COSV58042880; called by muse, mutect2, varscan2
- IGKV6-21 | c.195C>T p.L65= | Silent (SNP) | VAF 86/284 reads (30%) | called by muse, mutect2, varscan2
- KANK4 | c.1575C>A p.G525= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV62986724; called by muse, mutect2
- KCNC2 | c.990G>T p.V330= | Silent (SNP) | VAF 80/272 reads (29%) | catalogued as rs201237451, COSV54368802, COSV54371035; called by muse, mutect2, varscan2
- LPO | c.21C>G p.L7= | Silent (SNP) | VAF 185/561 reads (33%) | catalogued as rs915639744, COSV51858708; called by muse, mutect2, varscan2
- LRFN1 | c.486C>T p.S162= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50442446; called by muse, mutect2
- LRRC40 | c.1107C>A p.I369= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV63942268; called by muse, mutect2, varscan2
- MAN2A1 | c.1161C>T p.P387= | Silent (SNP) | VAF 62/111 reads (56%) | catalogued as rs753323721, COSV54851444; called by muse, mutect2, varscan2
- MUC3A | c.7356C>G p.V2452= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1563067680, COSV60215561; called by muse, mutect2, varscan2
- NCKAP5 | c.4116C>T p.I1372= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs759881752, COSV58443152; called by muse, mutect2, varscan2
- NOS3 | c.1494A>G p.E498= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52489607; called by muse, mutect2, varscan2
- OR2A25 | c.168C>A p.T56= | Silent (SNP) | VAF 200/432 reads (46%) | catalogued as COSV68717161; called by muse, mutect2, varscan2
- OR2G6 | c.597C>T p.L199= | Silent (SNP) | VAF 65/219 reads (30%) | catalogued as COSV100598337, COSV58573901; called by muse, mutect2, varscan2
- OR5D13 | c.861G>T p.L287= | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as COSV62333662; called by muse, mutect2, varscan2
- P3H1 | c.1959A>T p.S653= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV52533681; called by muse, mutect2, varscan2
- PEX5 | c.1242C>T p.T414= (on ENST00000420616; = p.T406= on NM_000319.5) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV56954930, COSV99870896; called by muse, mutect2, varscan2
- PLCH1 | c.2397A>T p.V799= (on ENST00000340059 / NM_001130960.2; = p.V811= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/226 reads (13%) | catalogued as COSV58196835; called by muse, mutect2, varscan2
- POU2F1 | c.1890A>G p.L630= (on ENST00000541643 / NM_001365848.1; = p.L653= on NM_002697.4) | Silent (SNP) | VAF 102/363 reads (28%) | catalogued as rs754961256, COSV54816928; called by muse, mutect2, varscan2
- PRDM15 | c.441G>A p.R147= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- PRELID2 | c.144A>G p.T48= (on ENST00000334744 / NM_182960.4; = p.T19= on NM_138492.6) | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as rs577387442, COSV58279861; called by muse, mutect2, varscan2
- PSKH2 | c.576T>C p.Y192= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV52610440; called by muse, mutect2, varscan2
- PZP | c.4182T>C p.G1394= | Silent (SNP) | VAF 123/347 reads (35%) | catalogued as COSV54360278; called by muse, mutect2, varscan2
- RELN | c.4902T>C p.S1634= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV58984554; called by muse, mutect2
- RYR3 | c.12459C>T p.T4153= (on ENST00000389232; = p.T4154= on NM_001036.6) | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs756142838, COSV66786520; called by muse, mutect2
- SIGLEC10 | c.261G>T p.R87= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV59481549; called by muse, mutect2
- SLC22A2 | c.372C>T p.D124= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs1406195900, COSV65266308; called by muse, mutect2, varscan2
- SLC4A10 | c.711T>C p.R237= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV55777874; called by muse, mutect2, varscan2
- SOCS5 | c.309C>A p.T103= | Silent (SNP) | VAF 94/222 reads (42%) | catalogued as COSV100125547, COSV60604836; called by muse, mutect2, varscan2
- ST6GAL2 | c.975T>C p.S325= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as COSV62416593; called by muse, mutect2
- STX16 | c.954C>G p.V318= (on ENST00000371141 / NM_001001433.3; = p.V297= on NM_003763.6) | Silent (SNP) | VAF 101/195 reads (52%) | catalogued as COSV56605736; called by muse, mutect2, varscan2
- SYMPK | c.2472G>A p.L824= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1366995109, COSV55611529, COSV99841263; called by muse, mutect2, varscan2
- TMEM132B | c.732G>T p.S244= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as rs752253408, COSV54753397; called by muse, mutect2, varscan2
- TRANK1 | c.2433C>T p.I811= | Silent (SNP) | VAF 199/414 reads (48%) | catalogued as COSV57149798; called by muse, mutect2, varscan2
- TTN | c.95742C>A p.L31914= (on ENST00000591111; = p.L24490= on NM_003319.4) | Silent (SNP) | VAF 105/267 reads (39%) | catalogued as COSV60049789; called by muse, mutect2, varscan2
- VCPIP1 | c.3315G>A p.Q1105= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV60047242; called by muse, mutect2, varscan2
- VEPH1 | c.1521A>T p.S507= | Silent (SNP) | VAF 52/361 reads (14%) | catalogued as COSV62878814; called by muse, mutect2, varscan2
- VPS13B | c.7299T>C p.S2433= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV62141381; called by muse, mutect2, varscan2
- VPS13D | c.12633G>A p.V4211= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1031467181, COSV50637809; called by muse, mutect2
- WDR49 | c.450A>T p.A150= (on ENST00000308378 / NM_001366158.1; = p.A491= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 465/1139 reads (41%) | catalogued as COSV57708088; called by muse, mutect2, varscan2
- ZNF131 | c.1704C>A p.T568= (on ENST00000509156 / NM_001330707.2; = p.T534= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV61002445; called by muse, mutect2, varscan2
- AC073310.1 | n.976C>A | RNA (SNP) | VAF 120/269 reads (45%) | called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039820 T>G | 5'Flank (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- SNORD116-20 | n.11T>A | RNA (SNP) | VAF 172/575 reads (30%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.16C>A | RNA (SNP) | VAF 96/236 reads (41%) | called by mutect2, varscan2
- TRPM3 | c.1816-903A>G | Intron (SNP) | VAF 36/103 reads (35%) | catalogued as COSV62585600; called by muse, mutect2, varscan2
- TTN | c.10361-4215C>A | Intron (SNP) | VAF 119/457 reads (26%) | catalogued as rs397517820, COSV60050110; called by muse, mutect2, varscan2
